Somatic mutation profile of tumor specimen 0D97WJ from CCDI case PBBIHA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.3 years (2,288 days).
Specimen 0D97WJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c48b2be-af77-4a17-ae28-380f7e578394.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D97WK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbef4f67-bfe0-475b-a5cb-a64a77bdf787

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 3, Missense Mutation 3, Silent 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LINC02210-CRHR1 | c.218T>C p.I73T | Missense Mutation (SNP) | VAF 21/452 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs757790713; called by muse, mutect2
- LRRC10 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762144273; called by muse, mutect2, varscan2
- MOGAT3 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs763725968, COSV56173670; called by muse, mutect2
- MS4A14 | c.899C>A p.S300* | Nonsense Mutation (SNP) | VAF 48/686 reads (7%) | catalogued as COSV55738791; called by muse, mutect2
- FBXO25 | c.406C>T p.Q136* (on ENST00000382824 / NM_183421.2; = p.Q69* on NM_012173.3) | Nonsense Mutation (SNP) | VAF 204/691 reads (30%) | called by muse, mutect2, varscan2
- UBR4 | c.8161C>T p.R2721* | Nonsense Mutation (SNP) | VAF 23/671 reads (3%) | called by muse, mutect2
- CASZ1 | c.4353G>A p.S1451= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs968154002; called by muse, mutect2, varscan2
- PHF12 | c.303G>C p.R101= | Silent (SNP) | VAF 20/582 reads (3%) | called by muse, mutect2
- BEND2 | c.-71C>T | 5'UTR (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- DYNLRB1 | c.79+3781dup | Intron (INS) | VAF 27/136 reads (20%) | called by mutect2, varscan2
